Somatic mutation profile of tumor specimen TCGA-HT-A617-01A (aliquot TCGA-HT-A617-01A-11D-A29Q-08) from TCGA case TCGA-HT-A617, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 47.4 years (17,331 days).
Specimen TCGA-HT-A617-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 632198d0-375e-4c87-b559-5e7b160ec027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A617-10A (Blood Derived Normal), aliquot TCGA-HT-A617-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c85ff1ca-d409-4d01-8bab-4cb1a887df7a

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP3 | c.2189G>A p.R730Q (on ENST00000622464; = p.R766Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746151673, COSV68242981; called by muse, mutect2, varscan2
- ATF7IP2 | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs140651559; called by muse, mutect2, varscan2
- CDH1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM130988, COSV55736502, COSV55745161; called by muse, mutect2, varscan2
- DCLK2 | c.1490A>G p.Y497C | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56211896; called by muse, mutect2, varscan2
- DENND1B | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs759023347, COSV52462619; called by muse, mutect2, varscan2
- ELAPOR1 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV64047060; called by muse, mutect2, varscan2
- KIAA1109 | c.10765C>T p.R3589C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1203575481, COSV52681632; called by muse, mutect2, varscan2
- MED1 | c.3265G>A p.V1089M | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV56128395; called by muse, mutect2, varscan2
- NRP2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55930279, COSV99785994; called by muse, mutect2, varscan2
- PCBP1 | c.1033G>C p.A345P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV57851855; called by muse, mutect2, varscan2
- PEA15 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | catalogued as COSV58785826; called by muse, mutect2, varscan2
- SHROOM2 | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as COSV66610548; called by muse, mutect2, varscan2
- SREK1 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); catalogued as COSV52335134; called by muse, mutect2, varscan2
- TMEM150C | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV71389511; called by muse, mutect2, varscan2
- AOX1 | c.1518G>A p.S506= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs748850939, COSV65980486; called by muse, mutect2, varscan2
- COL5A1 | c.3780C>T p.S1260= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs150591401; ClinVar: likely benign; called by muse, mutect2, varscan2
- FCRL5 | c.2391G>A p.S797= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs760916744, COSV62513993; called by muse, mutect2, varscan2
- KCNU1 | c.870G>T p.R290= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV67759694; called by muse, mutect2, varscan2
- NFXL1 | c.2601T>A p.R867= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV67432766; called by muse, mutect2, varscan2
- NISCH | c.18C>T p.T6= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51768401; called by muse, varscan2
- PKHD1L1 | c.6996A>G p.T2332= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV65752455; called by muse, mutect2
- CHRM2 | c.-47+33783G>A | Intron (SNP) | VAF 13/130 reads (10%) | catalogued as rs902318414, COSV57777714; called by muse, mutect2, varscan2
- GUK1 | c.-3+389G>A | Intron (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
